Somatic mutation profile of tumor specimen TARGET-50-PAJNGH-01A (aliquot TARGET-50-PAJNGH-01A-01D) from TARGET case TARGET-50-PAJNGH, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.3 years (851 days).
Specimen TARGET-50-PAJNGH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63ac90e3-ecc9-46d8-afcf-bdec7125fa9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJNGH-10A (Blood Derived Normal), aliquot TARGET-50-PAJNGH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cc69ce4-2f88-4d87-8e93-3652436d702b

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Nonsense Mutation 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.4139C>A p.S1380* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV62321398; called by muse, mutect2
- ADCY5 | c.2406G>T p.L802F | Missense Mutation (SNP) | VAF 106/218 reads (49%) | SIFT tolerated (0.73); PolyPhen benign (0.017); catalogued as COSV59198610; called by muse, mutect2, varscan2
- MANF | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56504276; called by muse, mutect2, varscan2
- MBP | c.850C>A p.L284I (on ENST00000355994 / NM_001025101.2; = p.L166I on NM_002385.3) | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV62828565; called by muse, mutect2
- RNF115 | c.275G>T p.S92I | Missense Mutation (SNP) | VAF 229/968 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV65164663; called by muse, mutect2, varscan2
- MAN2B1 | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 3/6 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SHROOM2 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by mutect2, varscan2
- SMC1A | c.1495C>G p.R499G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- TFPI | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 14/309 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.096); called by muse, mutect2
- ARL13A | c.609C>A p.I203= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV65880183; called by muse, mutect2, varscan2
- KLK12 | c.*103G>T | 3'UTR (SNP) | VAF 21/222 reads (9%) | called by muse, mutect2
